ORGANOID case 70 — Pancreas Cancer Organoid Profiling (ORGANOID-PANCREATIC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Primary site: Pancreas.
https://portal.gdc.cancer.gov/cases/f3aa1797-24fc-4fd1-a9f0-35acbc767562

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Biospecimens (2 samples)
- Samples S110, S215 (2 with the same recorded description): Sample type: Next Generation Cancer Model; Tissue type: Normal; Specimen type: 3D Organoid.
